Gene-level copy-number profile of tumor specimen TCGA-DK-AA6P-01A from TCGA case TCGA-DK-AA6P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,560 days).
Specimen TCGA-DK-AA6P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.928492ef-06da-4060-874c-25a59ffe7724.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,719 have no estimate.
https://portal.gdc.cancer.gov/files/57af1e05-3b96-4780-9314-6b1b56396479

Most common (modal) total copy number across autosomal genes: 7 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1; copy number 3: 2,354; copy number 4: 9,865; copy number 5: 14,619; copy number 6: 10,304; copy number 7: 19,761.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6P-01A-11D-A390-01): tumor purity 0.83, ploidy 5.73, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 15, i.e. more than twice the modal value of 7; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
